Somatic mutation profile of tumor specimen TCGA-BF-A3DM-01A (aliquot TCGA-BF-A3DM-01A-11D-A20D-08) from TCGA case TCGA-BF-A3DM, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 63.2 years (23,076 days).
Specimen TCGA-BF-A3DM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e376f447-0a94-435b-b1a0-fd2d7cfcb967.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BF-A3DM-10A (Blood Derived Normal), aliquot TCGA-BF-A3DM-10A-02D-A20D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e9f71c71-bd2a-47fc-993d-1163f7c2d0da

The open-access MAF lists 566 somatic variants for this specimen: 344 protein-altering or splice-affecting, 202 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 312, Silent 202, Nonsense Mutation 22, Intron 9, Splice Region 4, Splice Site 4, 3'Flank 3, RNA 3, 3'UTR 2, Frame Shift Ins 2, 5'UTR 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRAF | c.1918G>A p.V640M (on ENST00000288602 / NM_001374244.1; = p.V600M on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs121913378, COSV56066607, COSV56075762, COSV56124012, COSV56152883; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MMUT | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs772552898, CM050683, COSV99222325; ClinVar: pathogenic; called by muse, varscan2
- ABCA8 | c.1114G>A p.G372R | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52203949, COSV99285988; called by muse, mutect2, varscan2
- ABCB4 | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.62); PolyPhen benign (0.113); catalogued as rs377268767; called by muse, mutect2, varscan2
- ABCC3 | c.1330C>T p.L444F | Missense Mutation (SNP) | VAF 81/171 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53323901; called by muse, mutect2, varscan2
- AC126283.2 | c.1039C>A p.Q347K | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV67098953; called by muse, mutect2, varscan2
- ACLY | c.1781T>G p.I594S | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as COSV61251172; called by muse, mutect2, varscan2
- ADA | c.351G>A p.W117* | Nonsense Mutation (SNP) | VAF 39/74 reads (53%) | catalogued as COSV65740250; called by muse, mutect2, varscan2
- ADAM28 | c.235C>T p.L79F | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.547); catalogued as COSV56098294, COSV99739427; called by muse, mutect2, varscan2
- ADAM7 | c.2071C>T p.R691C | Missense Mutation (SNP) | VAF 49/107 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.732); catalogued as rs777631956, COSV51535626; called by muse, mutect2, varscan2
- ADAMTS16 | c.1129G>A p.G377R | Missense Mutation (SNP) | VAF 65/148 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763625032, COSV56993680; called by muse, mutect2
- ADCY1 | c.3250G>A p.G1084S | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as COSV52032135, COSV52036309; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.824G>A p.G275E | Missense Mutation (SNP) | VAF 61/156 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1347674535, COSV58444430; called by muse, mutect2, varscan2
- ADD2 | c.43C>T p.P15S | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV52463283; called by muse, mutect2, varscan2
- AFF1 | c.1739C>T p.P580L | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as COSV57120937; called by muse, mutect2, varscan2
- ALDH1L2 | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV51556883; called by muse, mutect2, varscan2
- ALPK2 | c.2413G>A p.E805K | Missense Mutation (SNP) | VAF 80/91 reads (88%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as COSV64493930; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.2848G>A p.E950K | Missense Mutation (SNP) | VAF 92/216 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.022); catalogued as COSV51850449; called by muse, mutect2, varscan2
- ANKRD33 | c.541G>A p.D181N (on ENST00000340970 / NM_001304459.2; = p.D306N on NM_182608.4) | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV56604953, COSV56606981; called by muse, mutect2
- ANO1 | c.926G>A p.G309E | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV60285875; called by muse, mutect2, varscan2
- APCDD1L | c.1147G>A p.G383R | Missense Mutation (SNP) | VAF 59/150 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.536); catalogued as rs1241764943, COSV64486784; called by muse, mutect2, varscan2
- ARHGAP44 | c.1580G>A p.R527Q | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.618); catalogued as rs1190588910, COSV52395766; called by muse, mutect2, varscan2
- ARHGEF10 | c.637C>T p.R213* (on ENST00000398564; = p.R188* on NM_014629.4) | Nonsense Mutation (SNP) | VAF 60/185 reads (32%) | catalogued as rs866229552, COSV50655445; called by muse, mutect2, varscan2
- ARID2 | c.3778G>T p.E1260* | Nonsense Mutation (SNP) | VAF 38/71 reads (54%) | catalogued as COSV57606696; called by muse, mutect2, varscan2
- ASB10 | c.388G>A p.E130K (on ENST00000420175 / NM_001142459.2; = p.E115K on NM_080871.4) | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.403); catalogued as COSV51997048; called by muse, mutect2, varscan2
- ATG2A | c.4735C>T p.R1579C | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1294786629, COSV65967201; called by muse, mutect2, varscan2
- ATIC | c.378T>A p.I126= | Splice Region (SNP) | VAF 12/36 reads (33%) | catalogued as COSV52693740; called by muse, mutect2, varscan2
- ATP10B | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.162); catalogued as COSV58779224; called by muse, mutect2, varscan2
- ATP2B2 | c.2972T>A p.F991Y (on ENST00000352432; = p.F957Y on NM_001683.5) | Missense Mutation (SNP) | VAF 96/212 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59499311; called by muse, mutect2, varscan2
- ATP2B2 | c.2441G>A p.G814E (on ENST00000352432; = p.G780E on NM_001683.5) | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59499334; called by muse, mutect2, varscan2
- ATP2B2 | c.860C>T p.T287I | Missense Mutation (SNP) | VAF 138/327 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59499352; called by muse, mutect2, varscan2
- ATP8B4 | c.332A>T p.N111I | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV52717764; called by muse, mutect2, varscan2
- ATR | c.5635G>A p.D1879N | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.659); catalogued as CS131233, COSV63387566; called by muse, mutect2, varscan2
- BBOX1 | c.196G>A p.G66S | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV54191671; called by muse, mutect2, varscan2
- BBS7 | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 129/276 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs756538454, COSV52657255; called by muse, mutect2, varscan2
- BCL11B | c.1241C>T p.P414L (on ENST00000357195 / NM_001282237.2; = p.P343L on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT tolerated (0.05); PolyPhen benign (0.053); catalogued as COSV61736384, COSV61736639; called by muse, mutect2, varscan2
- BRSK2 | c.1096G>A p.D366N | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57544345; called by muse, mutect2, varscan2
- BRWD1 | c.2785C>T p.P929S | Missense Mutation (SNP) | VAF 54/103 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV60897765; called by muse, mutect2, varscan2
- BTK | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 44/49 reads (90%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as COSV58120912; called by muse, mutect2, varscan2
- C12orf40 | c.913A>G p.I305V | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.078); catalogued as COSV61133638; called by muse, mutect2, varscan2
- C19orf18 | c.249G>A p.M83I | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.39); PolyPhen benign (0.011); catalogued as COSV58705497; called by muse, mutect2, varscan2
- C1S | c.1948G>A p.A650T | Missense Mutation (SNP) | VAF 76/200 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.355); catalogued as COSV61071212; called by muse, mutect2, varscan2
- C6 | c.2168G>A p.R723K | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV54712016; called by muse, mutect2, varscan2
- CACNA1C | c.4712G>C p.R1571T | Missense Mutation (SNP) | VAF 66/163 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as COSV59732276; called by muse, mutect2, varscan2
- CASP14 | c.289G>A p.G97R | Missense Mutation (SNP) | VAF 50/145 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55665737; called by muse, mutect2, varscan2
- CATSPERB | c.2494C>T p.L832F | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.06); catalogued as rs745440114, COSV56428312; called by muse, mutect2, varscan2
- CCDC93 | c.1733A>G p.E578G | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.267); catalogued as COSV60121963; called by muse, mutect2, varscan2
- CD6 | c.1978G>A p.D660N | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.163); catalogued as rs745322690, COSV57839689; called by muse, mutect2, varscan2
- CDC25B | c.921+1G>C p.X307_splice (on ENST00000245960 / NM_021873.3; = p.X293_splice on NM_004358.4) | Splice Site (SNP) | VAF 17/38 reads (45%) | catalogued as COSV55657398; called by muse, mutect2, varscan2
- CDH5 | c.1060G>A p.G354R | Missense Mutation (SNP) | VAF 109/125 reads (87%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV58518096; called by muse, mutect2, varscan2
- CDK8 | c.277G>A p.V93M | Missense Mutation (SNP) | VAF 82/223 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67419388, COSV67419755, COSV67422527; called by muse, mutect2, varscan2
- CDYL2 | c.936T>A p.D312E | Missense Mutation (SNP) | VAF 29/34 reads (85%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.511); catalogued as COSV73654307; called by muse, mutect2, varscan2
- CEP250 | c.3010G>A p.D1004N | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs752918699, COSV61170994; called by muse, mutect2, varscan2
- CFAP45 | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs770746064, COSV63649520; called by muse, mutect2, varscan2
- CFH | c.3292G>A p.E1098K | Missense Mutation (SNP) | VAF 81/256 reads (32%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.948); catalogued as rs545276741, COSV66409501; called by muse, mutect2, varscan2
- CLDN6 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV58509789; called by muse, mutect2, varscan2
- COL11A2 | c.518G>A p.R173Q | Missense Mutation (SNP) | VAF 54/149 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.235); catalogued as rs1165406140, COSV59498285; called by muse, mutect2, varscan2
- COL22A1 | c.847G>A p.D283N | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.915); catalogued as COSV57340903; called by muse, varscan2
- COMMD2 | c.244T>C p.F82L | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.913); catalogued as COSV71946516; called by muse, mutect2, varscan2
- CRB1 | c.428G>A p.R143K | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.86); PolyPhen benign (0.026); catalogued as CD011131, COSV66342781; called by muse, mutect2, varscan2
- CRPPA | c.964C>T p.H322Y (on ENST00000407010 / NM_001368197.1; = p.H272Y on NM_001101417.4) | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.129); catalogued as COSV67906719; called by muse, mutect2, varscan2
- CSMD1 | c.10579G>A p.E3527K (on ENST00000520002; = p.E3526K on NM_033225.6) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59287663, COSV59312285; called by muse, mutect2, varscan2
- CSMD2 | c.1152G>A p.M384I | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT tolerated (0.28); PolyPhen benign (0.103); catalogued as COSV53899698; called by muse, mutect2
- CSN2 | c.280C>T p.P94S | Missense Mutation (SNP) | VAF 67/148 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs980267132, COSV100778821, COSV61992322; called by muse, mutect2, varscan2
- CUL1 | c.610G>A p.V204I | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.6); catalogued as COSV57389624; called by muse, mutect2, varscan2
- CUL7 | c.2485C>T p.Q829* | Nonsense Mutation (SNP) | VAF 38/81 reads (47%) | catalogued as COSV54818504; called by muse, mutect2, varscan2
- CYP11B1 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as rs145050906; called by muse, mutect2, varscan2
- CYP11B2 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.023); catalogued as rs779011569, CM112768, COSV59996432; called by muse, mutect2, varscan2
- CYP7B1 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs866340497, COSV59582915; called by muse, mutect2, varscan2
- DCAF4L2 | c.64G>A p.G22R | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV60479690, COSV99081981; called by muse, mutect2, varscan2
- DDIT4 | c.433dup p.A145Gfs*50 | Frame Shift Ins (INS) | VAF 24/39 reads (62%) | catalogued as rs773055234; called by mutect2, pindel, varscan2
- DGLUCY | c.977C>T p.S326L | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as rs867294958, COSV56367199; called by muse, mutect2, varscan2
- DMRT3 | c.971C>T p.S324L | Missense Mutation (SNP) | VAF 31/42 reads (74%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs769032439, COSV51905568; called by muse, mutect2, varscan2
- DNAH10 | c.6730G>A p.E2244K (on ENST00000409039; = p.E2183K on NM_207437.3) | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV68995571; called by muse, mutect2, varscan2
- DNAH3 | c.9766G>A p.D3256N | Missense Mutation (SNP) | VAF 66/130 reads (51%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.638); catalogued as COSV99767321; called by muse, mutect2, varscan2
- DNAH5 | c.5282G>A p.R1761Q | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.019); catalogued as rs774020682, COSV54232685; called by muse, mutect2, varscan2
- DNAH5 | c.3824G>A p.G1275E | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.27); PolyPhen benign (0.052); catalogued as COSV54232708; called by muse, mutect2, varscan2
- DNAH7 | c.3232G>A p.E1078K | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56769872; called by muse, mutect2, varscan2
- DNALI1 | c.413G>A p.R138K (on ENST00000296218; = p.R116K on NM_003462.5) | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.444); catalogued as rs776150647, COSV56170268; called by muse, mutect2, varscan2
- DOCK2 | c.5455G>A p.G1819S | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs746762884, COSV56964867; called by muse, mutect2, varscan2
- DPYD | c.1740+1G>A p.X580_splice | Splice Site (SNP) | VAF 18/34 reads (53%) | catalogued as COSV64601791; called by muse, mutect2, varscan2
- DYNC1H1 | c.12213C>T p.I4071= | Splice Region (SNP) | VAF 26/56 reads (46%) | catalogued as rs746950373, COSV64138136; ClinVar: likely benign; called by muse, mutect2, varscan2
- EFCAB12 | c.878C>T p.P293L | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs376866624; called by muse, mutect2, varscan2
- EFCAB12 | c.877C>T p.P293S | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV58178689; called by muse, mutect2, varscan2
- EFNB3 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56833677; called by muse, mutect2, varscan2
- EIF4E | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 89/223 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV55187739, COSV55188133; called by muse, mutect2
- ENOX1 | c.1306C>T p.L436F | Missense Mutation (SNP) | VAF 49/99 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs979363984, COSV54903581; called by muse, mutect2, varscan2
- ENPP1 | c.2585C>T p.T862I | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV62933302; called by muse, mutect2, varscan2
- ENPP5 | c.1250C>T p.P417L | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs1354392455, COSV57909042; called by muse, mutect2, varscan2
- ENTHD1 | c.574G>A p.G192R | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs752962089, COSV57321558; called by muse, varscan2
- EPHA10 | c.174G>A p.W58* | Nonsense Mutation (SNP) | VAF 27/61 reads (44%) | catalogued as COSV60404127; called by muse, mutect2, varscan2
- EPS8L1 | c.1308G>A p.W436* (on ENST00000201647 / NM_133180.3; = p.W309* on NM_017729.3) | Nonsense Mutation (SNP) | VAF 4/19 reads (21%) | catalogued as COSV99136149; called by muse, mutect2, varscan2
- EPS8L1 | c.1309G>A p.E437K (on ENST00000201647 / NM_133180.3; = p.E310K on NM_017729.3) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV99136157; called by muse, mutect2, varscan2
- ERICH3 | c.2056G>A p.E686K | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.028); catalogued as COSV58609878, COSV58615836; called by muse, mutect2, varscan2
- ESPNL | c.1228G>A p.A410T | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as rs780751922, COSV58035602; called by muse, mutect2, varscan2
- EXPH5 | c.3431C>T p.T1144I | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV99761601; called by muse, mutect2, varscan2
- FAM13C | c.508-1G>A p.X170_splice | Splice Site (SNP) | VAF 50/59 reads (85%) | catalogued as COSV53250509; called by muse, mutect2, varscan2
- FAM183A | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as rs749476366, COSV58922362; called by muse, mutect2, varscan2
- FARP1 | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV60340118; called by muse, mutect2, varscan2
- FGD6 | c.46C>T p.P16S | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV59694134; called by muse, mutect2, varscan2
- FHOD1 | c.541C>T p.L181F | Missense Mutation (SNP) | VAF 31/35 reads (89%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV50762284; called by muse, mutect2, varscan2
- FLT4 | c.2485G>A p.E829K | Missense Mutation (SNP) | VAF 83/184 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV56102924, COSV56119986; called by muse, varscan2
- FMN2 | c.1315C>T p.Q439* | Nonsense Mutation (SNP) | VAF 100/186 reads (54%) | catalogued as COSV60434920; called by muse, mutect2, varscan2
- FNIP1 | c.1300C>T p.R434C | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.222); catalogued as rs757970564, COSV57197421; called by muse, mutect2, varscan2
- FSD1 | c.189A>C p.E63D | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as COSV55696661; called by muse, mutect2, varscan2
- GGN | c.1100A>G p.N367S | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.271); catalogued as COSV53057400; called by muse, mutect2
- GLI1 | c.143C>T p.S48F | Missense Mutation (SNP) | VAF 106/285 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as COSV57363639; called by muse, mutect2, varscan2
- GLI3 | c.3173G>A p.R1058Q | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs760174184, COSV67885478, COSV67885819; called by muse, mutect2, varscan2
- GNB1L | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.809); catalogued as rs769991918, COSV61548782; called by muse, mutect2, varscan2
- GPHN | c.1520G>A p.G507E (on ENST00000315266 / NM_001377519.1; = p.G540E on NM_020806.5) | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59483500; called by muse, mutect2, varscan2
- GPR15 | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV52520785; called by muse, mutect2, varscan2
- GPR78 | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs558447540, COSV66763279; called by muse, mutect2, varscan2
- GPR83 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.21); catalogued as rs768999557, COSV54719089; called by muse, mutect2, varscan2
- GRM3 | c.1598C>T p.P533L | Missense Mutation (SNP) | VAF 114/259 reads (44%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.755); catalogued as COSV64473779; called by muse, mutect2, varscan2
- GTF3C1 | c.4837G>A p.E1613K | Missense Mutation (SNP) | VAF 68/157 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as COSV62242116; called by muse, mutect2, varscan2
- GUCY2D | c.2320G>A p.D774N | Missense Mutation (SNP) | VAF 61/144 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.919); catalogued as COSV54696778; called by muse, mutect2, varscan2
- HCN1 | c.2573C>T p.P858L | Missense Mutation (SNP) | VAF 62/126 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.086); catalogued as COSV57517178; called by muse, mutect2, varscan2
- HDGFL2 | c.535C>T p.Q179* | Nonsense Mutation (SNP) | VAF 36/73 reads (49%) | catalogued as COSV56683342; called by muse, mutect2, varscan2
- HERC1 | c.4166T>A p.F1389Y | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV71248426; called by muse, mutect2, varscan2
- HIF3A | c.994G>A p.E332K (on ENST00000377670 / NM_152795.4; = p.E263K on NM_022462.4) | Missense Mutation (SNP) | VAF 56/134 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.67); catalogued as COSV52197654; called by muse, mutect2, varscan2
- HMCN1 | c.5473C>T p.P1825S | Missense Mutation (SNP) | VAF 41/145 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV54909503; called by muse, mutect2, varscan2
- IFT140 | c.3539C>T p.S1180F | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.316); catalogued as COSV63698288; called by muse, mutect2, varscan2
- IGKV1-17 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 60/189 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.282); catalogued as rs765745645; called by muse, mutect2, varscan2
- IL17RA | c.2453A>C p.E818A | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV60054186; called by muse, mutect2, varscan2
- IL17RD | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV56339173; called by muse, mutect2, varscan2
- IRX2 | c.698C>T p.S233L | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.582); catalogued as rs1183301386, COSV57411784; called by muse, mutect2, varscan2
- IRX5 | c.298C>T p.H100Y | Missense Mutation (SNP) | VAF 28/43 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as COSV58059188; called by muse, mutect2, varscan2
- ITGA2 | c.2864G>A p.G955E | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56861336; called by muse, mutect2, varscan2
- KARS1 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as COSV56692777; called by muse, mutect2, varscan2
- KAT14 | c.1567G>A p.D523N | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT tolerated (0.65); PolyPhen benign (0.045); catalogued as COSV66608086; called by muse, mutect2, varscan2
- KCNE3 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); catalogued as COSV100035635, COSV59552085; called by muse, mutect2, varscan2
- KCNJ5 | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs778087673, COSV57967196; called by muse, mutect2, varscan2
- KIAA1217 | c.1891C>T p.P631S | Missense Mutation (SNP) | VAF 26/33 reads (79%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs778851686, COSV56822404; called by muse, mutect2, varscan2
- KIAA1217 | c.1892C>T p.P631L | Missense Mutation (SNP) | VAF 26/33 reads (79%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV56824754; called by muse, mutect2, varscan2
- KIF22 | c.1205C>T p.A402V | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.065); catalogued as rs937292144, COSV99361115; called by muse, mutect2, varscan2
- KLF15 | c.1106C>T p.S369L | Missense Mutation (SNP) | VAF 18/25 reads (72%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs1560036365, COSV56179099, COSV56179630; called by muse, mutect2, varscan2
- KLHL21 | c.1550C>T p.S517F | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); catalogued as rs1219825842, COSV66553679; called by muse, mutect2, varscan2
- KRT15 | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 60/131 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as COSV54178060, COSV54179083; called by muse, mutect2, varscan2
- KRT18 | c.712G>A p.D238N | Missense Mutation (SNP) | VAF 34/59 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); catalogued as COSV66316267; called by muse, mutect2, varscan2
- KRT31 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 58/128 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as rs375534950; called by muse, mutect2, varscan2
- KRTAP12-3 | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 68/191 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs921779131, COSV100553377; called by muse, mutect2, varscan2
- KRTAP5-2 | c.299C>T p.S100F | Missense Mutation (SNP) | VAF 80/290 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.328); catalogued as COSV69014838; called by muse, varscan2
- KRTAP5-2 | c.269C>T p.S90F | Missense Mutation (SNP) | VAF 70/329 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.549); catalogued as COSV69015029; called by muse, varscan2
- KY | c.1630G>A p.E544K | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.163); catalogued as COSV71017668; called by muse, mutect2, varscan2
- LAMA2 | c.602C>T p.S201L | Missense Mutation (SNP) | VAF 51/98 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV104436767, COSV70347675; called by muse, mutect2, varscan2
- LARP1 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 30/83 reads (36%) | PolyPhen benign (0); catalogued as COSV60428127; called by muse, mutect2, varscan2
- LARP4 | c.1102C>T p.R368* | Nonsense Mutation (SNP) | VAF 17/45 reads (38%) | catalogued as COSV53323532; called by muse, mutect2, varscan2
- LIMK2 | c.1090C>T p.R364* | Nonsense Mutation (SNP) | VAF 13/32 reads (41%) | catalogued as rs114127458, COSV59181311; called by muse, mutect2, varscan2
- LMO7 | c.625G>A p.G209S (on ENST00000357063; = p.G224S on NM_005358.5) | Missense Mutation (SNP) | VAF 54/104 reads (52%) | SIFT tolerated (0.3); PolyPhen benign (0.121); catalogued as rs774821080, COSV58539585; called by muse, mutect2, varscan2
- LMOD3 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.059); catalogued as rs1239339268, COSV70456230; called by muse, mutect2, varscan2
- LPAR3 | c.738G>A p.G246= | Splice Region (SNP) | VAF 23/45 reads (51%) | catalogued as COSV65453978; called by muse, mutect2, varscan2
- LRP4 | c.1934C>T p.A645V | Missense Mutation (SNP) | VAF 69/180 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66136455; called by muse, mutect2, varscan2
- LYST | c.10205C>T p.T3402I | Missense Mutation (SNP) | VAF 167/325 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1171825438, COSV101089325; called by muse, mutect2, varscan2
- MACROH2A1 | c.32C>T p.T11I | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.348); catalogued as COSV56896121; called by muse, mutect2, varscan2
- MAGEE2 | c.1472G>A p.R491Q | Missense Mutation (SNP) | VAF 26/28 reads (93%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs757100041, COSV64897913; called by muse, mutect2, varscan2
- MAP3K19 | c.3743C>T p.S1248L | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59639730; called by muse, mutect2, varscan2
- MAP3K5 | c.3308G>A p.R1103Q | Missense Mutation (SNP) | VAF 52/100 reads (52%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.978); catalogued as rs78303756, COSV62889847; called by muse, mutect2, varscan2
- MAP7 | c.1949G>A p.G650E | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.866); catalogued as COSV63418375; called by muse, mutect2, varscan2
- MECOM | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV72110610; called by muse, mutect2, varscan2
- MEP1A | c.1648G>A p.V550M | Missense Mutation (SNP) | VAF 68/155 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.17); catalogued as COSV57920688; called by muse, mutect2, varscan2
- METTL16 | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54014306; called by muse, mutect2, varscan2
- MMP1 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 51/112 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.096); catalogued as COSV59510438; called by muse, mutect2, varscan2
- MORC1 | c.2551-2A>T p.X851_splice | Splice Site (SNP) | VAF 36/70 reads (51%) | catalogued as COSV51722362; called by muse, mutect2, varscan2
- MOV10L1 | c.892G>A p.G298R | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV53173593; called by muse, mutect2, varscan2
- MPZ | c.548G>A p.W183* | Nonsense Mutation (SNP) | VAF 68/156 reads (44%) | catalogued as COSV60668628; called by muse, mutect2, varscan2
- MROH2B | c.4256G>A p.G1419E | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.63); catalogued as COSV68185515; called by muse, mutect2, varscan2
- MS4A8 | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 86/192 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1426906759, COSV55753305; called by muse, mutect2, varscan2
- MTA3 | c.1345G>A p.G449R | Missense Mutation (SNP) | VAF 82/258 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV63196919; called by muse, mutect2, varscan2
- MUC15 | c.970A>G p.M324V | Missense Mutation (SNP) | VAF 54/117 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as COSV55555201; called by muse, mutect2, varscan2
- MUC16 | c.21262C>T p.P7088S | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV67473965; called by muse, mutect2, varscan2
- MUC16 | c.20926C>T p.P6976S | Missense Mutation (SNP) | VAF 55/115 reads (48%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.021); catalogued as COSV67468007; called by muse, mutect2, varscan2
- MUC17 | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 80/185 reads (43%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as rs542185793, COSV60292082; called by muse, mutect2, varscan2
- MUC17 | c.12311C>T p.S4104F | Missense Mutation (SNP) | VAF 70/166 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.03); catalogued as rs868211635, COSV60292092; called by muse, mutect2, varscan2
- MYBPC2 | c.2113G>A p.E705K | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1210268372, COSV63096569; called by muse, mutect2, varscan2
- MYCL | c.203G>T p.C68F (on ENST00000372816 / NM_001033081.3; = p.C98F on NM_005376.5) | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.52); PolyPhen benign (0.137); catalogued as COSV65693410, COSV65693474; called by muse, mutect2, varscan2
- MYEOV | c.332G>A p.G111E | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as rs1369100374, COSV58293717; called by muse, mutect2, varscan2
- MYH1 | c.4585G>A p.E1529K | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV56843424, COSV56850652; called by muse, mutect2, varscan2
- MYO18B | c.6539C>T p.T2180I | Missense Mutation (SNP) | VAF 77/157 reads (49%) | SIFT tolerated (0.4); PolyPhen benign (0.044); catalogued as COSV59137742; called by muse, mutect2, varscan2
- NBR1 | c.1370C>T p.S457F | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV57833343; called by muse, mutect2, varscan2
- NCKAP1L | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53207390; called by muse, mutect2, varscan2
- NELL1 | c.790T>G p.L264V | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.978); catalogued as COSV54278081; called by muse, mutect2, varscan2
- NEXMIF | c.1883G>A p.R628Q | Missense Mutation (SNP) | VAF 20/20 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747436946, COSV50021850; called by muse, mutect2, varscan2
- NHSL2 | c.1565C>T p.P522L (on ENST00000510661; = p.P888L on NM_001013627.2) | Missense Mutation (SNP) | VAF 26/31 reads (84%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); catalogued as COSV65453867; called by muse, mutect2, varscan2
- NID1 | c.442C>T p.Q148* | Nonsense Mutation (SNP) | VAF 23/60 reads (38%) | catalogued as COSV51622319; called by muse, mutect2, varscan2
- NID2 | c.4070G>A p.R1357Q | Missense Mutation (SNP) | VAF 52/119 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.124); catalogued as rs149021065; called by muse, mutect2, varscan2
- NLRP1 | c.3556C>T p.H1186Y | Missense Mutation (SNP) | VAF 50/95 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52568920; called by muse, mutect2, varscan2
- NOC2L | c.985C>T p.L329F | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs577506851, COSV58988261; called by muse, mutect2, varscan2
- NOS2 | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 55/144 reads (38%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.555); catalogued as COSV58224681; called by muse, mutect2, varscan2
- NOTCH4 | c.2236C>T p.P746S | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT tolerated (0.05); PolyPhen benign (0.059); catalogued as COSV66681535; called by muse, mutect2, varscan2
- NPY5R | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as rs990663503, COSV58452444; called by muse, mutect2, varscan2
- NUP160 | c.1903C>T p.P635S | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV65854727; called by muse, mutect2, varscan2
- NWD1 | c.2329C>T p.P777S | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.549); catalogued as COSV60344434; called by muse, mutect2, varscan2
- OAF | c.773T>G p.V258G | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV61108782, COSV61109444; called by muse, mutect2, varscan2
- OBSCN | c.10178G>A p.W3393* | Nonsense Mutation (SNP) | VAF 45/183 reads (25%) | catalogued as COSV52785553; called by muse, mutect2, varscan2
- OR10A7 | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV58278833; called by muse, mutect2, varscan2
- OR10H3 | c.64C>T p.Q22* | Nonsense Mutation (SNP) | VAF 122/286 reads (43%) | catalogued as COSV59944162; called by muse, mutect2, varscan2
- OR10J3 | c.965C>T p.S322F | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100171595, COSV59954087; called by muse, mutect2, varscan2
- OR2G6 | c.53C>T p.S18L | Missense Mutation (SNP) | VAF 101/192 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as rs1300866484, COSV58574878; called by muse, mutect2, varscan2
- OR2J2 | c.26C>T p.S9L | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as rs200829397, COSV65848101; called by muse, mutect2, varscan2
- OR2J2 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 135/378 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65848103; called by muse, mutect2, varscan2
- OR2T1 | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 65/113 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV63542230; called by muse, mutect2, varscan2
- OR4C15 | c.346T>G p.L116V (on ENST00000314644; = p.L62V on NM_001001920.2) | Missense Mutation (SNP) | VAF 75/153 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV58952394, COSV58952408, COSV58954071; called by muse, mutect2, varscan2
- OR4C46 | c.302G>A p.G101E | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.036); catalogued as COSV60219914; called by muse, mutect2, varscan2
- OR52E4 | c.460A>T p.N154Y | Missense Mutation (SNP) | VAF 53/107 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.37); catalogued as COSV57625190; called by muse, mutect2, varscan2
- OR52R1 | c.56G>A p.G19E | Missense Mutation (SNP) | VAF 35/61 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61887462; called by muse, mutect2, varscan2
- OR5AC2 | c.569C>T p.S190L | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV62279403; called by muse, mutect2, varscan2
- OR5H2 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs770093101, COSV62350222, COSV62350448; called by muse, mutect2, varscan2
- OR5H2 | c.704C>T p.S235F | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100788652, COSV62351058; called by muse, mutect2, varscan2
- OR5T3 | c.25G>A p.D9N | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.003); catalogued as COSV57381226; called by muse, mutect2, varscan2
- OR5V1 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs763921109, COSV65828473; called by muse, mutect2, varscan2
- OR8B2 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 43/184 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1204905683; called by muse, mutect2
- P2RX3 | c.314G>A p.G105E | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); catalogued as rs747101058, COSV54443178, COSV99628694; called by muse, mutect2, varscan2
- P2RY8 | c.275G>A p.G92E | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67177567; called by muse, mutect2, varscan2
- PAGE2 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 52/55 reads (95%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.492); catalogued as COSV66596047; called by muse, mutect2
- PATE1 | c.249G>A p.R83= | Splice Region (SNP) | VAF 25/58 reads (43%) | catalogued as COSV59824778; called by muse, mutect2, varscan2
- PCDH10 | c.2069G>A p.G690E | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.041); catalogued as COSV52096578, COSV52104373; called by muse, mutect2, varscan2
- PCDHA10 | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 76/178 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.043); catalogued as COSV56514351; called by muse, mutect2, varscan2
- PCDHB10 | c.428C>T p.S143L | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.03); catalogued as COSV53375368; called by muse, mutect2, varscan2
- PCSK4 | c.701G>A p.G234D | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52013802; called by muse, mutect2, varscan2
- PDLIM2 | c.784C>T p.P262S (on ENST00000397760; = p.P512S on NM_021630.6) | Missense Mutation (SNP) | VAF 28/45 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV56133414; called by muse, mutect2, varscan2
- PDZD2 | c.6026C>T p.P2009L | Missense Mutation (SNP) | VAF 111/285 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.162); catalogued as COSV56861485; called by muse, mutect2, varscan2
- PEX5L | c.919A>G p.T307A | Missense Mutation (SNP) | VAF 51/112 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV55848323; called by muse, mutect2, varscan2
- PGK2 | c.373C>T p.H125Y | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.233); catalogued as rs868088566, COSV59164339; called by muse, mutect2, varscan2
- PHLDB2 | c.551C>T p.S184F | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV67312569; called by muse, mutect2, varscan2
- PKD1 | c.8027G>T p.R2676M | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV51918577; called by mutect2, varscan2
- PKP3 | c.1390C>T p.L464F | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.11); PolyPhen benign (0.383); catalogued as rs764386462, COSV58985754, COSV58987669; called by muse, mutect2, varscan2
- PLCL1 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.652); catalogued as COSV70839999; called by muse, mutect2, varscan2
- PLCZ1 | c.1513G>A p.D505N | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.366); catalogued as rs749285005, COSV56854152; called by muse, mutect2, varscan2
- POF1B | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 16/19 reads (84%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.998); catalogued as rs780528435, COSV53135555; called by muse, mutect2, varscan2
- POLA1 | c.3298C>T p.L1100F | Missense Mutation (SNP) | VAF 12/12 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs913112052, COSV66884411; called by muse, varscan2
- PPM1L | c.794G>A p.R265Q | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1214162439, COSV55565633; called by muse, mutect2, varscan2
- PPP1R13B | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.194); catalogued as rs775649972, COSV52448613, COSV52452895; called by muse, mutect2, varscan2
- PPP1R3A | c.2446G>A p.E816K | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as COSV52885038; called by muse, mutect2, varscan2
- PPP6C | c.163C>T p.H55Y | Missense Mutation (SNP) | VAF 97/115 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65207040; called by muse, mutect2, varscan2
- PRF1 | c.355C>T p.R119W | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as rs749110507, CM074979, COSV100942691, COSV64615209; called by muse, mutect2, varscan2
- PROKR1 | c.1065G>T p.K355N | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV58137978; called by muse, mutect2, varscan2
- PRPF40B | c.28C>T p.P10S (on ENST00000380281; = p.P4S on NM_012272.3) | Missense Mutation (SNP) | VAF 107/251 reads (43%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.992); catalogued as rs754841742, COSV99979794; called by muse, mutect2, varscan2
- PRPF40B | c.29C>T p.P10L (on ENST00000380281; = p.P4L on NM_012272.3) | Missense Mutation (SNP) | VAF 106/247 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV99979796; called by muse, mutect2, varscan2
- PRRG3 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 77/87 reads (89%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.656); catalogued as COSV64851176; called by muse, mutect2, varscan2
- PRUNE2 | c.7171C>T p.P2391S | Missense Mutation (SNP) | VAF 43/52 reads (83%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); catalogued as COSV65042916; called by muse, mutect2, varscan2
- PSG2 | c.946T>A p.L316M | Missense Mutation (SNP) | VAF 155/380 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as COSV61545588, COSV61546038; called by muse, mutect2, varscan2
- PTCH1 | c.757C>T p.P253S | Missense Mutation (SNP) | VAF 40/43 reads (93%) | SIFT tolerated (0.73); PolyPhen benign (0.028); catalogued as COSV59465688, COSV59479444; called by muse, mutect2, varscan2
- PTPRB | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as COSV54241749; called by muse, mutect2
- PTPRK | c.3262C>T p.R1088* (on ENST00000368215 / NM_001291984.2; = p.R1089* on NM_002844.4) | Nonsense Mutation (SNP) | VAF 57/123 reads (46%) | catalogued as COSV63900534; called by muse, mutect2, varscan2
- PTPRN2 | c.1747G>A p.E583K | Missense Mutation (SNP) | VAF 95/225 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV67020941; called by muse, mutect2, varscan2
- RAB11FIP1 | c.2502T>A p.C834* | Nonsense Mutation (SNP) | VAF 51/97 reads (53%) | catalogued as COSV54761074; called by muse, mutect2, varscan2
- RGS22 | c.1646C>T p.P549L | Missense Mutation (SNP) | VAF 59/142 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV62663370; called by muse, mutect2, varscan2
- RGS22 | c.898G>A p.D300N | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1432992104, COSV62663384; called by muse, mutect2, varscan2
- RNF32 | c.631A>C p.K211Q | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV58733142; called by muse, mutect2, varscan2
- RP1 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.314); catalogued as COSV55119195; called by muse, mutect2, varscan2
- RP1L1 | c.2894C>T p.P965L | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.101); catalogued as COSV66756431; called by muse, mutect2, varscan2
- RPE65 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs748546353, COSV52013547, COSV52015838, COSV52016741; called by muse, mutect2, varscan2
- RPIA | c.292C>T p.Q98* | Nonsense Mutation (SNP) | VAF 62/162 reads (38%) | catalogued as COSV52170137; called by muse, mutect2, varscan2
- RPUSD2 | c.869C>T p.S290F | Missense Mutation (SNP) | VAF 65/146 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV59765782; called by muse, mutect2, varscan2
- SCAF4 | c.518C>T p.S173F | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54588545, COSV54591875; called by muse, mutect2, varscan2
- SCN10A | c.2861C>T p.S954F | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.721); catalogued as COSV101479358; called by muse, mutect2
- SCN11A | c.4367C>T p.P1456L | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as COSV56572261; called by muse, mutect2, varscan2
- SCN1A | c.857C>T p.S286F | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.383); catalogued as COSV57674147; called by muse, mutect2, varscan2
- SCN2A | c.1158G>A p.W386* | Nonsense Mutation (SNP) | VAF 20/44 reads (45%) | catalogued as rs1375200092, COSV51845359; called by muse, mutect2, varscan2
- SCN3A | c.1336C>T p.Q446* | Nonsense Mutation (SNP) | VAF 49/90 reads (54%) | catalogued as rs1553535058, COSV51811259, COSV51813491; called by muse, mutect2, varscan2
- SERPINI2 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV52986760; called by muse, mutect2, varscan2
- SGSM1 | c.1499C>T p.S500F | Missense Mutation (SNP) | VAF 98/202 reads (49%) | SIFT tolerated (0.47); PolyPhen benign (0.26); catalogued as COSV68511072; called by muse, mutect2, varscan2
- SI | c.3721G>A p.E1241K | Missense Mutation (SNP) | VAF 35/58 reads (60%) | SIFT tolerated (0.23); PolyPhen benign (0.232); catalogued as rs1416779997, COSV52268181; called by muse, mutect2, varscan2
- SLC26A4 | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV55917470; called by muse, mutect2, varscan2
- SLC2A2 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV58586515; called by muse, mutect2
- SLC41A2 | c.820C>T p.H274Y | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV51606584; called by muse, mutect2, varscan2
- SLC49A4 | c.1262C>T p.T421I | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.719); catalogued as COSV53747607; called by muse, mutect2, varscan2
- SLC6A9 | c.997C>T p.R333C (on ENST00000360584 / NM_201649.4; = p.R279C on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs774639733, COSV62210053; called by muse, mutect2, varscan2
- SLC7A5 | c.809C>T p.P270L | Missense Mutation (SNP) | VAF 30/38 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55365066; called by muse, mutect2, varscan2
- SLC7A7 | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV53541167; called by muse, mutect2, varscan2
- SLC8A3 | c.1609G>A p.D537N | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT tolerated (0.4); PolyPhen benign (0.011); catalogued as COSV63522502; called by muse, mutect2, varscan2
- SLK | c.1141C>T p.L381F | Missense Mutation (SNP) | VAF 40/54 reads (74%) | SIFT tolerated (0.53); PolyPhen benign (0.109); catalogued as COSV59826261, COSV59826307; called by muse, mutect2, varscan2
- SLPI | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.65); PolyPhen benign (0.258); catalogued as COSV58092326; called by muse, mutect2, varscan2
- SMG8 | c.464C>T p.S155F | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV56285848; called by muse, mutect2, varscan2
- SNURF | c.104A>G p.N35S | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs752792774, COSV57597795; called by muse, mutect2, varscan2
- SPG11 | c.3394C>T p.P1132S | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.903); catalogued as rs891639488, COSV55992243, COSV55996757; called by muse, mutect2, varscan2
- SPSB1 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 168/336 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs866233336, COSV60163615; called by muse, mutect2, varscan2
- SPTA1 | c.6562G>A p.E2188K | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.497); catalogued as COSV63752174; called by muse, mutect2, varscan2
- SPTA1 | c.1127C>A p.S376* | Nonsense Mutation (SNP) | VAF 108/201 reads (54%) | catalogued as COSV63752900, COSV63755020; called by muse, varscan2
- SRCAP | c.7112C>T p.S2371F | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as rs540911812, COSV52674942; called by muse, mutect2, varscan2
- ST7 | c.1426C>T p.P476S (on ENST00000265437 / NM_021908.3; = p.P453S on NM_018412.4) | Missense Mutation (SNP) | VAF 77/187 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55386965; called by muse, mutect2, varscan2
- STK17B | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55828711; called by muse, mutect2, varscan2
- STPG2 | c.1141A>G p.R381G | Missense Mutation (SNP) | VAF 57/119 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.239); catalogued as COSV54802849, COSV54803241; called by muse, mutect2, varscan2
- SUN1 | c.1790G>A p.R597Q (on ENST00000405266 / NM_001367651.1; = p.R477Q on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs374707736; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYNM | c.2881C>T p.P961S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100152735; called by muse, mutect2, varscan2
- SYNM | c.2882C>T p.P961L | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100152736; called by muse, mutect2, varscan2
- SYVN1 | c.1769A>G p.E590G (on ENST00000377190 / NM_172230.3; = p.E589G on NM_032431.3) | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV53695817; called by muse, mutect2, varscan2
- SZT2 | c.400C>T p.R134W | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as rs1409830966, COSV60289662; called by muse, mutect2, varscan2
- TACC2 | c.2344C>T p.P782S | Missense Mutation (SNP) | VAF 60/73 reads (82%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.497); catalogued as rs1199597673, COSV57759240; called by muse, mutect2, varscan2
- TAS1R2 | c.800G>A p.S267N | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.935); catalogued as rs1237767350, COSV64745505; called by muse, mutect2, varscan2
- TAS2R1 | c.222A>T p.E74D | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.173); catalogued as COSV66778843; called by muse, mutect2, varscan2
- TENM3 | c.3403G>T p.E1135* | Nonsense Mutation (SNP) | VAF 11/44 reads (25%) | catalogued as COSV69311127; called by muse, mutect2, varscan2
- TEX19 | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT tolerated (0.63); PolyPhen benign (0.01); catalogued as COSV61017609; called by muse, mutect2, varscan2
- TGIF2LY | c.56G>A p.S19N | Missense Mutation (SNP) | VAF 31/42 reads (74%) | SIFT tolerated (0.09); PolyPhen benign (0.366); catalogued as COSV58291772; called by muse, mutect2, varscan2
- TIAM1 | c.2344C>G p.R782G | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as COSV54557216; called by muse, mutect2, varscan2
- TKTL2 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 70/164 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as COSV54919578; called by muse, mutect2, varscan2
- TLR10 | c.1381G>A p.E461K | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT tolerated (0.33); PolyPhen benign (0.043); catalogued as COSV58300945; called by muse, mutect2, varscan2
- TLR8 | c.905T>A p.I302N (on ENST00000218032 / NM_138636.5; = p.I320N on NM_016610.4) | Missense Mutation (SNP) | VAF 42/45 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV54318686; called by muse, mutect2, varscan2
- TM4SF5 | c.397G>A p.G133R | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV54497055; called by muse, mutect2, varscan2
- TMEM150A | c.758G>A p.G253E (on ENST00000334462 / NM_001031738.3; = p.G200E on NM_153342.3) | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.555); catalogued as COSV57818099; called by muse, mutect2, varscan2
- TMEM225 | c.258G>A p.M86I | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as COSV66693518; called by muse, mutect2, varscan2
- TNFRSF8 | c.405G>A p.M135I | Missense Mutation (SNP) | VAF 45/70 reads (64%) | SIFT tolerated (0.08); PolyPhen benign (0.122); catalogued as COSV55797382; called by muse, mutect2, varscan2
- TNRC6A | c.3200C>T p.P1067L | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.239); catalogued as COSV59366399; called by muse, mutect2, varscan2
- TNRC6C | c.4159C>T p.P1387S | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56947581; called by muse, mutect2, varscan2
- TRAK1 | c.2344C>T p.P782S | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV59643899; called by muse, mutect2, varscan2
- TRBV4-2 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 91/227 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs758688041; called by muse, mutect2, varscan2
- TRIM62 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.67); PolyPhen benign (0.025); catalogued as rs1191921675, COSV52221910; called by muse, mutect2, varscan2
- TRPC5 | c.1314G>A p.M438I | Missense Mutation (SNP) | VAF 63/71 reads (89%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.854); catalogued as COSV53293625; called by muse, mutect2, varscan2
- TRPM2 | c.2398C>T p.H800Y | Missense Mutation (SNP) | VAF 149/327 reads (46%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs1370209540, COSV55971350; called by muse, mutect2, varscan2
- TSEN2 | c.596G>A p.C199Y | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53189360, COSV53191558; called by muse, varscan2
- TSHZ2 | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 83/210 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs201933484, COSV61589452; called by muse, mutect2, varscan2
- TTLL10 | c.431G>A p.G144E (on ENST00000379289 / NM_001130045.2; = p.G71E on NM_153254.3) | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.006); catalogued as rs1244334463, COSV64960213; called by muse, mutect2, varscan2
- TTLL10 | c.1234G>A p.D412N (on ENST00000379289 / NM_001130045.2; = p.D339N on NM_153254.3) | Missense Mutation (SNP) | VAF 130/296 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.403); catalogued as rs372449382; called by muse, varscan2
- TTN | c.58802G>A p.G19601E (on ENST00000591111; = p.G12177E on NM_003319.4) | Missense Mutation (SNP) | VAF 10/27 reads (37%) | PolyPhen probably damaging (1); catalogued as COSV60134625; called by muse, mutect2, varscan2
- TTN | c.40807G>A p.E13603K (on ENST00000591111; = p.E6179K on NM_003319.4) | Missense Mutation (SNP) | VAF 20/52 reads (38%) | PolyPhen benign (0.001); catalogued as COSV60134666; called by muse, mutect2, varscan2
- TUFM | c.1043C>T p.S348F | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV57949156; called by muse, mutect2, varscan2
- UBFD1 | c.43A>G p.M15V | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); catalogued as COSV54842265; called by muse, mutect2
- UPK3B | c.199G>A p.G67R | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.007); catalogued as COSV56861695, COSV99991064; called by muse, mutect2, varscan2
- UROC1 | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 59/139 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.236); catalogued as COSV52034810; called by muse, mutect2, varscan2
- USP28 | c.2828C>T p.S943F | Missense Mutation (SNP) | VAF 64/147 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV50167134; called by muse, mutect2, varscan2
- VPS13B | c.10286C>T p.P3429L | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV62145986; called by muse, mutect2, varscan2
- VWA3A | c.2315G>A p.R772K | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.039); catalogued as COSV55391941; called by muse, mutect2, varscan2
- WASF1 | c.1355C>T p.P452L | Missense Mutation (SNP) | VAF 62/161 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs568812903, COSV63935690; called by muse, mutect2, varscan2
- WIF1 | c.997C>A p.H333N | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV54132802; called by mutect2, varscan2
- WWC1 | c.1582C>T p.P528S | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.875); catalogued as COSV54652740; called by muse, mutect2, varscan2
- XKR3 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 73/162 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.64); catalogued as COSV58887151, COSV58888315; called by muse, mutect2, varscan2
- YTHDC2 | c.3790C>T p.P1264S | Missense Mutation (SNP) | VAF 65/150 reads (43%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as COSV50743672; called by muse, mutect2
- ZBTB34 | c.1180C>T p.H394Y | Missense Mutation (SNP) | VAF 21/27 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100043505, COSV59860060; called by muse, mutect2, varscan2
- ZDHHC23 | c.830T>A p.I277K | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV57629702; called by muse, mutect2, varscan2
- ZFAT | c.2365G>A p.V789I | Missense Mutation (SNP) | VAF 58/156 reads (37%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.995); catalogued as rs753877810, COSV64740492; called by muse, mutect2, varscan2
- ZFC3H1 | c.4633C>T p.P1545S | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs1211006208, COSV66431148; called by muse, mutect2, varscan2
- ZGLP1 | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0.05); PolyPhen benign (0.284); catalogued as rs995626995, COSV58533277; called by muse, mutect2, varscan2
- ZNF229 | c.655G>A p.D219N | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT tolerated (0.53); PolyPhen benign (0.037); catalogued as COSV52162774; called by muse, mutect2, varscan2
- ZNF300 | c.1612G>A p.G538R | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.53); PolyPhen benign (0.018); catalogued as COSV51037097; called by muse, mutect2, varscan2
- ZNF34 | c.568C>T p.P190S | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV58638670; called by muse, mutect2, varscan2
- ZNF341 | c.2477C>T p.S826F (on ENST00000375200 / NM_001282935.1; = p.S819F on NM_032819.4) | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.08); catalogued as rs759202264, COSV61009380; called by muse, mutect2, varscan2
- ZNF425 | c.2234C>T p.A745V | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.589); catalogued as COSV65201621; called by muse, mutect2, varscan2
- ZNF676 | c.557C>T p.S186L (on ENST00000650058; = p.S154L on NM_001001411.3) | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.918); catalogued as rs754813419, COSV68093483; called by muse, mutect2, varscan2
- FCGBP | c.11602C>T p.P3868S | Missense Mutation (SNP) | VAF 100/256 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- GAS2L2 | c.2533G>A p.E845K | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGHV4-61 | c.165G>A p.W55* | Nonsense Mutation (SNP) | VAF 56/72 reads (78%) | called by muse, mutect2, varscan2
- IGKV2-24 | c.50G>A p.G17E | Missense Mutation (SNP) | VAF 52/129 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- LDHA | c.51_52dup p.T18Rfs*24 | Frame Shift Ins (INS) | VAF 21/63 reads (33%) | called by mutect2, pindel, varscan2
- ACSM1 | c.1599G>A p.L533= | Silent (SNP) | VAF 92/192 reads (48%) | catalogued as COSV54636927; called by muse, mutect2, varscan2
- ACSM2B | c.585G>A p.K195= | Silent (SNP) | VAF 93/240 reads (39%) | catalogued as COSV61656870, COSV61658390; called by muse, mutect2, varscan2
- ADAMTS16 | c.1131G>A p.G377= | Silent (SNP) | VAF 65/150 reads (43%) | catalogued as rs753335605, COSV56993692; called by muse, mutect2
- ADAMTS7 | c.3550C>T p.L1184= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as COSV66307816; called by muse, mutect2, varscan2
- ADGRB1 | c.1908C>T p.S636= | Silent (SNP) | VAF 52/115 reads (45%) | catalogued as rs1248141310, COSV60098354; called by muse, mutect2, varscan2
- ADGRE5 | c.1206C>T p.L402= (on ENST00000242786 / NM_078481.4; = p.L309= on NM_001784.5) | Silent (SNP) | VAF 76/179 reads (42%) | catalogued as COSV54412086, COSV54415444; called by muse, mutect2, varscan2
- ADGRV1 | c.3924C>T p.F1308= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as rs1326674504, COSV67981159; called by muse, mutect2, varscan2
- ADH7 | c.456C>T p.F152= | Silent (SNP) | VAF 93/209 reads (44%) | catalogued as rs760759023, COSV52920319; called by muse, mutect2, varscan2
- AIFM1 | c.1197C>T p.G399= | Silent (SNP) | VAF 33/36 reads (92%) | catalogued as COSV54855536; called by muse, mutect2, varscan2
- ALDH9A1 | c.450C>T p.S150= | Silent (SNP) | VAF 46/73 reads (63%) | catalogued as rs1258652965, COSV61339921; called by muse, mutect2, varscan2
- ALPK3 | c.5100G>A p.K1700= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as COSV51934834; called by muse, mutect2, varscan2
- AMER3 | c.1236C>T p.F412= | Silent (SNP) | VAF 29/55 reads (53%) | catalogued as COSV58467698; called by muse, mutect2, varscan2
- ANK3 | c.8535A>C p.G2845= | Silent (SNP) | VAF 38/49 reads (78%) | catalogued as COSV55063534; called by muse, mutect2, varscan2
- AP002512.3 | c.495C>T p.F165= | Silent (SNP) | VAF 23/52 reads (44%) | catalogued as COSV54407110; called by muse, varscan2
- AP002512.3 | c.447C>T p.I149= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as COSV54406774; called by muse, varscan2
- APOL1 | c.1008G>A p.T336= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as rs373044647, COSV59869247; called by muse, mutect2, varscan2
- ATP2A1 | c.2679C>T p.A893= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as COSV62869820; called by muse, mutect2, varscan2
- ATP8A1 | c.2838A>G p.L946= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV52538210; called by muse, mutect2, varscan2
- ATRNL1 | c.3696G>A p.Q1232= | Silent (SNP) | VAF 9/15 reads (60%) | catalogued as COSV58093807; called by muse, mutect2, varscan2
- BDKRB2 | c.906C>T p.S302= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as rs1345939835, COSV60015058, COSV60015323; called by muse, mutect2, varscan2
- BOD1L1 | c.4887C>T p.D1629= | Silent (SNP) | VAF 91/185 reads (49%) | catalogued as COSV50019560; called by muse, mutect2, varscan2
- BPIFA3 | c.30C>T p.I10= | Silent (SNP) | VAF 39/100 reads (39%) | catalogued as COSV64925962; called by muse, mutect2, varscan2
- C9orf24 | c.100C>T p.L34= | Silent (SNP) | VAF 76/84 reads (90%) | catalogued as COSV52621255; called by muse, mutect2, varscan2
- CA5B | c.924C>T p.P308= | Silent (SNP) | VAF 64/76 reads (84%) | catalogued as COSV59416731; called by muse, mutect2, varscan2
- CAMK4 | c.330C>T p.T110= | Silent (SNP) | VAF 34/130 reads (26%) | catalogued as COSV56674022; called by muse, mutect2, varscan2
- CAMKK2 | c.153C>T p.S51= | Silent (SNP) | VAF 30/57 reads (53%) | catalogued as rs1225600865, COSV61215602; called by muse, mutect2, varscan2
- CARD11 | c.1962C>T p.T654= | Silent (SNP) | VAF 30/64 reads (47%) | catalogued as COSV62755690; called by muse, mutect2, varscan2
- CCDC181 | c.945G>A p.G315= | Silent (SNP) | VAF 96/167 reads (57%) | catalogued as COSV63156893; called by muse, mutect2, varscan2
- CCDC43 | c.393C>T p.L131= | Silent (SNP) | VAF 63/183 reads (34%) | catalogued as COSV59520104; called by muse, mutect2, varscan2
- CDC42BPG | c.3261C>T p.N1087= | Silent (SNP) | VAF 45/133 reads (34%) | catalogued as rs987430462, COSV61347820; called by muse, mutect2, varscan2
- CDH23 | c.4911C>T p.P1637= | Silent (SNP) | VAF 12/14 reads (86%) | catalogued as COSV56470937; called by muse, mutect2, varscan2
- CDH23 | c.5157C>T p.I1719= | Silent (SNP) | VAF 41/51 reads (80%) | catalogued as COSV56470953; called by muse, mutect2, varscan2
- CDK8 | c.276G>A p.K92= | Silent (SNP) | VAF 80/223 reads (36%) | catalogued as COSV101037226; called by muse, mutect2, varscan2
- CES2 | c.1263C>T p.L421= | Silent (SNP) | VAF 50/68 reads (74%) | catalogued as COSV57697101; called by muse, mutect2, varscan2
- CFAP46 | c.7209C>T p.I2403= | Silent (SNP) | VAF 9/10 reads (90%) | catalogued as rs758726257, COSV54154022; called by muse, mutect2, varscan2
- CGN | c.3045C>T p.D1015= | Silent (SNP) | VAF 68/121 reads (56%) | catalogued as COSV54970744, COSV54974125; called by muse, mutect2, varscan2
- CGN | c.3261C>T p.I1087= | Silent (SNP) | VAF 64/113 reads (57%) | catalogued as COSV54970751; called by muse, mutect2, varscan2
- CHRM2 | c.693T>A p.V231= | Silent (SNP) | VAF 19/33 reads (58%) | catalogued as COSV57775271; called by muse, mutect2, varscan2
- CHRNB2 | c.729C>T p.I243= | Silent (SNP) | VAF 98/305 reads (32%) | catalogued as COSV63808525, COSV63808794; called by muse, mutect2, varscan2
- CLDN19 | c.651C>T p.S217= | Silent (SNP) | VAF 12/22 reads (55%) | catalogued as rs752738519, COSV56417368; called by mutect2, varscan2
- CLDN9 | c.265C>T p.L89= | Silent (SNP) | VAF 33/78 reads (42%) | catalogued as COSV60911006; called by muse, mutect2, varscan2
- CNGA2 | c.388C>T p.L130= | Silent (SNP) | VAF 135/153 reads (88%) | catalogued as COSV61702995, COSV61705058; called by muse, mutect2, varscan2
- CNTN3 | c.936C>T p.L312= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV55171449; called by muse, mutect2, varscan2
- CNTN5 | c.2175C>T p.I725= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as COSV54320849; called by muse, mutect2, varscan2
- COL20A1 | c.2502C>T p.L834= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV58919309; called by muse, mutect2, varscan2
- COL6A3 | c.2958C>T p.I986= | Silent (SNP) | VAF 79/183 reads (43%) | catalogued as rs145203676; called by muse, mutect2, varscan2
- CPAMD8 | c.2244G>A p.V748= (on ENST00000651564; = p.V701= on NM_015692.5) | Silent (SNP) | VAF 45/116 reads (39%) | catalogued as COSV52235906; called by muse, mutect2, varscan2
- CPXM2 | c.915G>A p.R305= | Silent (SNP) | VAF 53/65 reads (82%) | catalogued as COSV53864230; called by muse, mutect2, varscan2
- CRNN | c.223C>T p.L75= | Silent (SNP) | VAF 68/112 reads (61%) | catalogued as COSV55122490; called by muse, mutect2, varscan2
- CXCR6 | c.255C>T p.P85= | Silent (SNP) | VAF 88/181 reads (49%) | catalogued as rs1156909574, COSV56116953; called by muse, mutect2, varscan2
- CYP2F1 | c.261C>T p.A87= | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as COSV58527907; called by muse, mutect2, varscan2
- DDX24 | c.2398C>T p.L800= | Silent (SNP) | VAF 55/124 reads (44%) | catalogued as COSV52573810; called by muse, mutect2, varscan2
- DHDDS | c.361C>T p.L121= | Silent (SNP) | VAF 50/113 reads (44%) | catalogued as rs770824761, COSV52577119; called by muse, mutect2, varscan2
- DMD | c.1498C>T p.L500= | Silent (SNP) | VAF 22/26 reads (85%) | catalogued as COSV55879198; called by muse, mutect2, varscan2
- DNAH17 | c.1731G>A p.L577= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV104433107, COSV67756820; called by muse, mutect2, varscan2
- DNAH2 | c.10014C>T p.I3338= | Silent (SNP) | VAF 44/105 reads (42%) | catalogued as rs774648799, COSV66718526; called by muse, mutect2, varscan2
- DNAH3 | c.9765G>A p.E3255= | Silent (SNP) | VAF 64/129 reads (50%) | catalogued as COSV99767324; called by muse, mutect2, varscan2
- DNAH5 | c.4563G>A p.E1521= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as COSV54232695, COSV54255675; called by muse, mutect2, varscan2
- DSCAM | c.2481C>T p.I827= | Silent (SNP) | VAF 69/178 reads (39%) | catalogued as COSV68025272, COSV68029181; called by muse, mutect2, varscan2
- EBF2 | c.822C>T p.I274= | Silent (SNP) | VAF 45/108 reads (42%) | catalogued as rs1313952654, COSV68776712; called by muse, mutect2, varscan2
- ELMO1 | c.912C>A p.L304= | Silent (SNP) | VAF 54/104 reads (52%) | catalogued as COSV60308921; called by muse, mutect2, varscan2
- ERBB4 | c.27C>G p.V9= | Silent (SNP) | VAF 60/146 reads (41%) | catalogued as COSV53543435; called by muse, mutect2, varscan2
- ERICH6 | c.135G>A p.E45= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as rs1370183681, COSV55801296; called by muse, mutect2, varscan2
- EVC2 | c.3172C>T p.L1058= | Silent (SNP) | VAF 27/61 reads (44%) | catalogued as COSV60395714; called by muse, mutect2, varscan2
- EXPH5 | c.3432C>T p.T1144= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as rs547979885, COSV99761599; called by muse, mutect2, varscan2
- FAAH2 | c.600G>A p.Q200= | Silent (SNP) | VAF 94/106 reads (89%) | catalogued as COSV66508826; called by muse, mutect2, varscan2
- FAM161B | c.1899G>A p.L633= (on ENST00000651776; = p.L570= on NM_152445.3) | Silent (SNP) | VAF 69/161 reads (43%) | catalogued as COSV54102664; called by muse, mutect2, varscan2
- FAM47A | c.1491G>A p.K497= | Silent (SNP) | VAF 48/53 reads (91%) | catalogued as COSV60497634; called by muse, varscan2
- FBXL4 | c.600C>T p.F200= | Silent (SNP) | VAF 34/119 reads (29%) | catalogued as COSV57747606; called by muse, mutect2, varscan2
- FFAR3 | c.108G>A p.L36= | Silent (SNP) | VAF 58/277 reads (21%) | catalogued as COSV59909215; called by muse, varscan2
- FFAR3 | c.153C>T p.D51= | Silent (SNP) | VAF 68/316 reads (22%) | catalogued as rs372231935, COSV59908989; called by muse, varscan2
- FIBIN | c.147C>T p.P49= | Silent (SNP) | VAF 24/63 reads (38%) | catalogued as COSV59413047; called by muse, mutect2, varscan2
- FNDC8 | c.102C>T p.P34= | Silent (SNP) | VAF 50/119 reads (42%) | catalogued as COSV50101795; called by muse, mutect2
- FRAS1 | c.11334C>T p.F3778= | Silent (SNP) | VAF 28/71 reads (39%) | catalogued as COSV53603498; called by muse, mutect2, varscan2
- FZD7 | c.1086C>T p.F362= | Silent (SNP) | VAF 46/109 reads (42%) | catalogued as rs1448008298, COSV53809445; called by muse, mutect2, varscan2
- GABRB3 | c.639C>T p.I213= | Silent (SNP) | VAF 49/124 reads (40%) | catalogued as rs767178198, COSV54649133; called by muse, mutect2, varscan2
- GJB5 | c.483G>A p.V161= | Silent (SNP) | VAF 26/48 reads (54%) | catalogued as COSV58356443; called by muse, mutect2, varscan2
- GJC1 | c.609C>T p.V203= | Silent (SNP) | VAF 64/129 reads (50%) | catalogued as rs867907714, COSV57911635; called by muse, mutect2, varscan2
- GPHN | c.1704C>T p.I568= (on ENST00000315266 / NM_001377519.1; = p.I601= on NM_020806.5) | Silent (SNP) | VAF 114/273 reads (42%) | catalogued as COSV59483509; called by muse, mutect2, varscan2
- H4C7 | c.36G>A p.G12= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as COSV55100146; called by muse, mutect2, varscan2
- HAVCR1 | c.528G>A p.T176= | Silent (SNP) | VAF 390/840 reads (46%) | catalogued as rs1554091894, COSV59400649; called by muse, varscan2
- HECA | c.291C>T p.P97= | Silent (SNP) | VAF 111/234 reads (47%) | catalogued as COSV62769681; called by muse, mutect2, varscan2
- HEPH | c.2826C>T p.T942= (on ENST00000343002; = p.T675= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 69/73 reads (95%) | catalogued as rs949741124, COSV57965868; called by muse, mutect2, varscan2
- HYDIN | c.657G>A p.K219= | Silent (SNP) | VAF 12/14 reads (86%) | catalogued as COSV99863093; called by mutect2, varscan2
- IFNA14 | c.9G>A p.L3= | Silent (SNP) | VAF 56/74 reads (76%) | catalogued as rs1467421029, COSV66516217; called by muse, mutect2, varscan2
- IGSF9 | c.186C>T p.F62= | Silent (SNP) | VAF 52/108 reads (48%) | catalogued as COSV63640513; called by muse, mutect2, varscan2
- INSR | c.1099C>T p.L367= | Silent (SNP) | VAF 65/147 reads (44%) | catalogued as COSV57164850; called by muse, mutect2, varscan2
- ITGA10 | c.3004C>T p.L1002= | Silent (SNP) | VAF 67/129 reads (52%) | catalogued as COSV65197848; called by muse, mutect2, varscan2
- KAT14 | c.2067C>T p.F689= | Silent (SNP) | VAF 39/76 reads (51%) | catalogued as rs1568676631, COSV66608090; called by muse, mutect2, varscan2
- KCNJ2 | c.801C>T p.I267= | Silent (SNP) | VAF 28/69 reads (41%) | catalogued as COSV54662429; called by muse, mutect2, varscan2
- KCTD8 | c.1047G>A p.G349= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as COSV63590665; called by muse, mutect2, varscan2
- KEL | c.1200C>T p.P400= | Silent (SNP) | VAF 56/111 reads (50%) | catalogued as COSV62335778; called by muse, mutect2, varscan2
- KIAA1549 | c.2694C>T p.S898= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as COSV54317508; called by muse, mutect2, varscan2
- KIF22 | c.1206C>T p.A402= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as COSV50715778; called by muse, mutect2, varscan2
- KIRREL1 | c.1032G>A p.K344= | Silent (SNP) | VAF 30/116 reads (26%) | catalogued as rs1305051426, COSV63288154; called by muse, mutect2, varscan2
- KLK4 | c.219C>T p.F73= | Silent (SNP) | VAF 106/238 reads (45%) | catalogued as COSV60676536; called by muse, mutect2, varscan2
- KPTN | c.753C>T p.S251= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV57645336; called by muse, mutect2, varscan2
- KRT39 | c.876G>A p.E292= | Silent (SNP) | VAF 60/187 reads (32%) | catalogued as COSV62917454; called by muse, mutect2
- KRT8 | c.1239G>A p.T413= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as rs549571104, COSV53177746; called by muse, mutect2, varscan2
- KRTAP12-3 | c.111C>T p.P37= | Silent (SNP) | VAF 66/188 reads (35%) | catalogued as rs1387918181, COSV59978977; called by muse, mutect2, varscan2
- LRFN2 | c.2304G>A p.E768= | Silent (SNP) | VAF 45/110 reads (41%) | catalogued as rs372038448; called by muse, mutect2, varscan2
- LRRC32 | c.1827C>T p.S609= | Silent (SNP) | VAF 55/106 reads (52%) | catalogued as COSV52633535; called by muse, mutect2, varscan2
- LYST | c.10206C>T p.T3402= | Silent (SNP) | VAF 166/324 reads (51%) | catalogued as COSV101089323; called by muse, mutect2, varscan2
- MAGEA12 | c.859C>T p.L287= | Silent (SNP) | VAF 147/166 reads (89%) | catalogued as COSV63294921; called by muse, mutect2, varscan2
- MAGEB6 | c.978G>A p.G326= | Silent (SNP) | VAF 116/158 reads (73%) | catalogued as COSV66872461; called by muse, mutect2, varscan2
- MAP3K21 | c.900C>T p.T300= | Silent (SNP) | VAF 55/108 reads (51%) | catalogued as COSV64045151; called by muse, mutect2, varscan2
- MARS1 | c.453C>T p.A151= | Silent (SNP) | VAF 92/222 reads (41%) | catalogued as COSV56254448; called by muse, mutect2, varscan2
- MICAL3 | c.1956C>T p.S652= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as rs771528217, COSV52898950; called by muse, mutect2, varscan2
- MINAR1 | c.2403C>T p.S801= | Silent (SNP) | VAF 60/135 reads (44%) | catalogued as COSV59583849; called by muse, mutect2, varscan2
- MLKL | c.771C>T p.F257= | Silent (SNP) | VAF 18/21 reads (86%) | catalogued as rs568554020, COSV58204029; called by muse, mutect2, varscan2
- MMUT | c.1104C>T p.V368= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV99222328; called by muse, mutect2, varscan2
- MOCS1 | c.1893G>A p.G631= | Silent (SNP) | VAF 112/246 reads (46%) | catalogued as COSV51339412; called by muse, mutect2, varscan2
- MOCS1 | c.174C>T p.S58= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as rs776528157, COSV57937105; called by muse, mutect2, varscan2
- MRO | c.549G>A p.L183= | Silent (SNP) | VAF 158/177 reads (89%) | catalogued as COSV56496697; called by muse, mutect2, varscan2
- MROH2B | c.4476G>A p.V1492= | Silent (SNP) | VAF 52/99 reads (53%) | catalogued as COSV68185510; called by muse, mutect2, varscan2
- MRPL54 | c.33G>A p.R11= | Silent (SNP) | VAF 35/79 reads (44%) | catalogued as COSV57462921; called by muse, mutect2, varscan2
- MUC16 | c.32094C>T p.I10698= | Silent (SNP) | VAF 97/220 reads (44%) | catalogued as COSV67473950; called by muse, mutect2, varscan2
- MUC16 | c.22725C>T p.S7575= | Silent (SNP) | VAF 60/165 reads (36%) | catalogued as COSV67466722; called by muse, mutect2, varscan2
- MYBPC2 | c.1773G>A p.R591= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV63096563; called by muse, mutect2, varscan2
- MYH1 | c.4311G>A p.E1437= | Silent (SNP) | VAF 50/151 reads (33%) | catalogued as COSV56850661; called by muse, mutect2, varscan2
- MYH9 | c.5614C>T p.L1872= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV53387980; called by mutect2, varscan2
- MYPN | c.2811C>T p.I937= | Silent (SNP) | VAF 35/36 reads (97%) | catalogued as rs151242284, COSV62734949, COSV62740728; called by muse, mutect2, varscan2
- MYT1L | c.1005C>T p.F335= | Silent (SNP) | VAF 33/79 reads (42%) | catalogued as rs752574419, COSV67710458; called by muse, mutect2, varscan2
- NAA11 | c.81G>A p.Q27= | Silent (SNP) | VAF 26/66 reads (39%) | catalogued as COSV54514526, COSV54514831; called by muse, mutect2, varscan2
- NAV1 | c.3792T>C p.A1264= | Silent (SNP) | VAF 76/250 reads (30%) | catalogued as COSV55219506; called by muse, mutect2, varscan2
- NCR3 | c.30C>T p.I10= | Silent (SNP) | VAF 39/100 reads (39%) | catalogued as rs774390040, COSV53001210; called by muse, mutect2, varscan2
- NEK8 | c.1104C>T p.L368= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as rs1052596453, COSV52045709; called by muse, mutect2, varscan2
- NEUROD1 | c.420C>T p.I140= | Silent (SNP) | VAF 27/64 reads (42%) | catalogued as COSV54549852; called by muse, mutect2, varscan2
- NHLH1 | c.258C>T p.I86= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as COSV57483813; called by muse, mutect2
- NLRC5 | c.1653C>G p.T551= | Silent (SNP) | VAF 67/81 reads (83%) | catalogued as COSV52657340; called by muse, mutect2, varscan2
- NLRP13 | c.1575C>T p.I525= | Silent (SNP) | VAF 23/52 reads (44%) | catalogued as COSV100738029; called by muse, mutect2, varscan2
- NLRP8 | c.1173C>T p.S391= | Silent (SNP) | VAF 48/136 reads (35%) | catalogued as rs267605705, COSV52589212; called by muse, mutect2, varscan2
- NOD2 | c.1782G>A p.G594= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as COSV56051968; called by muse, mutect2, varscan2
- NPEPL1 | c.1461C>T p.F487= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as rs373873091; called by muse, mutect2, varscan2
- NR0B2 | c.639C>T p.R213= | Silent (SNP) | VAF 36/107 reads (34%) | catalogued as COSV54259815; called by muse, mutect2, varscan2
- NTRK3 | c.1350C>T p.F450= | Silent (SNP) | VAF 27/97 reads (28%) | catalogued as COSV58122720; called by muse, mutect2, varscan2
- OAS2 | c.306G>A p.G102= | Silent (SNP) | VAF 39/86 reads (45%) | catalogued as COSV60802888; called by muse, mutect2, varscan2
- OR5AS1 | c.312C>T p.F104= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as rs142110904; called by muse, mutect2, varscan2
- OR6Y1 | c.246C>T p.I82= | Silent (SNP) | VAF 61/165 reads (37%) | catalogued as COSV56929827; called by muse, mutect2, varscan2
- OSMR | c.345G>A p.K115= | Silent (SNP) | VAF 27/64 reads (42%) | catalogued as COSV57086536; called by muse, mutect2, varscan2
- OXER1 | c.1089C>T p.L363= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV54311427; called by muse, mutect2, varscan2
- PAPPA | c.1212C>T p.S404= | Silent (SNP) | VAF 39/55 reads (71%) | catalogued as rs1400306160, COSV60285838; called by muse, mutect2, varscan2
- PCDHA12 | c.1578G>A p.E526= | Silent (SNP) | VAF 92/225 reads (41%) | catalogued as COSV56514380; called by muse, mutect2, varscan2
- PCNX1 | c.4761C>T p.I1587= | Silent (SNP) | VAF 265/575 reads (46%) | catalogued as COSV53089607; called by muse, mutect2, varscan2
- PILRA | c.55C>T p.L19= | Silent (SNP) | VAF 59/132 reads (45%) | catalogued as COSV52200193; called by muse, mutect2, varscan2
- PLAGL2 | c.180C>T p.L60= | Silent (SNP) | VAF 32/79 reads (41%) | catalogued as rs758631247, COSV55788745; called by muse, mutect2, varscan2
- POU5F2 | c.240G>A p.R80= | Silent (SNP) | VAF 11/19 reads (58%) | catalogued as COSV67938815; called by muse, mutect2, varscan2
- PRAG1 | c.1290G>A p.Q430= | Silent (SNP) | VAF 36/91 reads (40%) | catalogued as COSV58162580; called by muse, mutect2, varscan2
- PRAMEF14 | c.891C>T p.N297= | Silent (SNP) | VAF 29/99 reads (29%) | called by muse, mutect2, varscan2
- PRAMEF4 | c.114C>T p.F38= | Silent (SNP) | VAF 58/155 reads (37%) | catalogued as rs775270846, COSV52439205; called by muse, mutect2, varscan2
- PRKG2 | c.966C>T p.T322= | Silent (SNP) | VAF 35/76 reads (46%) | catalogued as COSV52325982; called by muse, mutect2, varscan2
- PRPF8 | c.4620G>T p.P1540= | Silent (SNP) | VAF 44/101 reads (44%) | catalogued as COSV59264258; called by muse, mutect2, varscan2
- PTPRO | c.216G>A p.E72= | Silent (SNP) | VAF 26/48 reads (54%) | catalogued as COSV55513037; called by muse, mutect2, varscan2
- RNF185 | c.567C>T p.L189= | Silent (SNP) | VAF 37/104 reads (36%) | catalogued as COSV56735881; called by muse, mutect2, varscan2
- RNF32 | c.354C>T p.L118= | Silent (SNP) | VAF 35/84 reads (42%) | catalogued as COSV58733116; called by muse, mutect2, varscan2
- RTEL1 | c.207C>T p.A69= | Silent (SNP) | VAF 34/90 reads (38%) | catalogued as rs957858006, COSV58896180; called by muse, mutect2, varscan2
- SAMD7 | c.597G>A p.E199= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as COSV59419442; called by muse, mutect2, varscan2
- SASH3 | c.687G>A p.V229= | Silent (SNP) | VAF 24/24 reads (100%) | catalogued as COSV63556082; called by muse, mutect2, varscan2
- SCN10A | c.2862C>T p.S954= | Silent (SNP) | VAF 42/84 reads (50%) | catalogued as COSV101479379; called by muse, mutect2
- SCN2A | c.2619C>T p.I873= | Silent (SNP) | VAF 39/75 reads (52%) | catalogued as rs868404050, CM165173, COSV51845378; called by muse, mutect2, varscan2
- SCN4A | c.4356G>A p.L1452= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as rs754606856, COSV71127381; called by muse, mutect2, varscan2
- SDHA | c.414C>T p.A138= | Silent (SNP) | VAF 35/96 reads (36%) | catalogued as rs1219265195, COSV53769667; ClinVar: likely benign; called by muse, mutect2, varscan2
- SEC11C | c.240C>T p.F80= | Silent (SNP) | VAF 186/220 reads (85%) | catalogued as COSV55311676; called by muse, mutect2, varscan2
- SETD7 | c.933C>T p.P311= | Silent (SNP) | VAF 67/135 reads (50%) | catalogued as COSV56800741; called by muse, mutect2, varscan2
- SF3B2 | c.1008C>T p.P336= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as COSV59428672; called by muse, mutect2, varscan2
- SHISAL1 | c.531G>A p.Q177= | Silent (SNP) | VAF 76/148 reads (51%) | catalogued as COSV66988106; called by muse, mutect2, varscan2
- SLC17A8 | c.1338C>T p.A446= | Silent (SNP) | VAF 60/158 reads (38%) | catalogued as COSV60124581; called by muse, mutect2, varscan2
- SLC1A3 | c.1269C>T p.F423= | Silent (SNP) | VAF 48/98 reads (49%) | catalogued as rs758802146, COSV54317468; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC1A7 | c.84C>T p.I28= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as rs985167612, COSV65194328; called by muse, mutect2, varscan2
- SLC24A4 | c.519C>T p.I173= | Silent (SNP) | VAF 55/159 reads (35%) | catalogued as rs768955114, COSV54106994; called by muse, mutect2, varscan2
- SLC25A43 | c.543C>T p.S181= | Silent (SNP) | VAF 83/90 reads (92%) | catalogued as COSV54218196; called by muse, mutect2, varscan2
- SLC34A2 | c.303G>A p.L101= | Silent (SNP) | VAF 51/120 reads (43%) | catalogued as COSV65941973; called by muse, mutect2, varscan2
- SLC50A1 | c.330G>A p.L110= | Silent (SNP) | VAF 38/145 reads (26%) | catalogued as COSV57597246; called by muse, mutect2, varscan2
- SLITRK3 | c.2229C>T p.I743= | Silent (SNP) | VAF 47/131 reads (36%) | catalogued as COSV53849468; called by muse, mutect2, varscan2
- SMPDL3A | c.213C>T p.S71= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as rs776374695, COSV63755482; called by muse, mutect2, varscan2
- SOGA1 | c.3453A>G p.E1151= | Silent (SNP) | VAF 43/115 reads (37%) | catalogued as COSV52921911; called by muse, mutect2, varscan2
- SOST | c.627G>A p.L209= | Silent (SNP) | VAF 21/46 reads (46%) | catalogued as COSV57012801; called by muse, mutect2, varscan2
- SSTR5 | c.388C>T p.L130= | Silent (SNP) | VAF 23/78 reads (29%) | catalogued as COSV53512488; called by muse, mutect2, varscan2
- STIMATE-MUSTN1 | c.984C>T p.S328= | Silent (SNP) | VAF 12/19 reads (63%) | catalogued as COSV56575396; called by muse, mutect2, varscan2
- SUZ12 | c.2043C>T p.L681= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as COSV59500917; called by muse, mutect2, varscan2
- SYN3 | c.1134G>A p.V378= | Silent (SNP) | VAF 41/96 reads (43%) | catalogued as COSV60510293; called by muse, mutect2, varscan2
- SYNE1 | c.3486G>A p.E1162= (on ENST00000367255 / NM_182961.4; = p.E1169= on NM_033071.3) | Silent (SNP) | VAF 44/95 reads (46%) | catalogued as COSV55011268; called by muse, mutect2, varscan2
- TDRD5 | c.1284A>T p.V428= | Silent (SNP) | VAF 80/141 reads (57%) | catalogued as COSV54244729, COSV99675782; called by muse, mutect2, varscan2
- THEMIS2 | c.387C>T p.L129= | Silent (SNP) | VAF 59/103 reads (57%) | catalogued as rs1258546442, COSV61077897; called by muse, mutect2, varscan2
- TMEM8B | c.1062G>A p.L354= | Silent (SNP) | VAF 73/89 reads (82%) | catalogued as COSV65076966; called by muse, mutect2, varscan2
- TMPRSS15 | c.1914G>A p.G638= | Silent (SNP) | VAF 76/179 reads (42%) | catalogued as COSV53041850; called by muse, mutect2, varscan2
- TNXB | c.7899C>T p.I2633= (on ENST00000647633; = p.I2386= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as rs201201973, COSV100926715, COSV64480973; called by muse, mutect2, varscan2
- TRANK1 | c.4707C>T p.G1569= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV57153644; called by muse, mutect2, varscan2
- TRIM13 | c.1072C>T p.L358= | Silent (SNP) | VAF 44/89 reads (49%) | catalogued as rs369999399, COSV53949947; called by muse, mutect2, varscan2
- TRIM42 | c.309C>T p.F103= | Silent (SNP) | VAF 23/45 reads (51%) | catalogued as COSV53884084; called by muse, mutect2, varscan2
- TRRAP | c.5193C>T p.F1731= (on ENST00000359863 / NM_001244580.1; = p.F1713= on NM_003496.3) | Silent (SNP) | VAF 32/77 reads (42%) | catalogued as rs1554417897, COSV62846597; called by muse, mutect2, varscan2
- TSPAN17 | c.786C>T p.L262= | Silent (SNP) | VAF 29/71 reads (41%) | catalogued as rs61753280, COSV53780704; called by muse, mutect2, varscan2
- TTN | c.28422G>A p.R9474= (on ENST00000591111; = p.R8547= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV60134710; called by muse, mutect2, varscan2
- TTN | c.609G>A p.K203= | Silent (SNP) | VAF 27/71 reads (38%) | catalogued as COSV100629607, COSV60134730; called by muse, mutect2, varscan2
- USH2A | c.9636C>T p.I3212= | Silent (SNP) | VAF 44/78 reads (56%) | catalogued as rs397518049, COSV56343578, COSV56425285; ClinVar: likely benign; called by muse, mutect2, varscan2
- USP26 | c.39G>A p.G13= | Silent (SNP) | VAF 34/37 reads (92%) | catalogued as rs187171762, COSV63708122; called by muse, mutect2, varscan2
- VSTM2A | c.480C>T p.F160= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as rs781550989, COSV56495044; called by muse, mutect2
- WNK4 | c.1182G>A p.P394= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as rs777411138, COSV55906084; called by muse, mutect2, varscan2
- XKR7 | c.945G>A p.L315= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as rs779012471, COSV73813238; called by muse, mutect2, varscan2
- ZDHHC23 | c.504C>T p.P168= | Silent (SNP) | VAF 82/167 reads (49%) | catalogued as rs575365066, COSV57629693; called by muse, mutect2, varscan2
- ZNF454 | c.1227G>A p.E409= | Silent (SNP) | VAF 40/106 reads (38%) | catalogued as COSV60768927; called by muse, mutect2, varscan2
- ZNF678 | c.786G>A p.E262= | Silent (SNP) | VAF 37/78 reads (47%) | catalogued as COSV59384227; called by muse, mutect2, varscan2
- ABCC9 | chr12:21801112 C>T | 3'Flank (SNP) | VAF 35/65 reads (54%) | catalogued as COSV53975420; called by muse, mutect2, varscan2
- C14orf177 | n.769G>A | RNA (SNP) | VAF 23/68 reads (34%) | catalogued as COSV57901154; called by muse, mutect2, varscan2
- CST9 | c.-1C>T | 5'UTR (SNP) | VAF 20/49 reads (41%) | catalogued as rs1293691982, COSV100980475; called by muse, mutect2, varscan2
- DHX30 | c.3192-36C>T | Intron (SNP) | VAF 23/47 reads (49%) | catalogued as COSV99275343; called by muse, mutect2, varscan2
- EVL | c.352+12034G>A | Intron (SNP) | VAF 7/28 reads (25%) | catalogued as COSV100762601; called by muse, mutect2, varscan2
- FBXL13 | c.496-5441A>G | Intron (SNP) | VAF 33/91 reads (36%) | catalogued as COSV100501585; called by muse, mutect2
- HERC2P3 | n.821G>A | RNA (SNP) | VAF 54/233 reads (23%) | called by muse, mutect2, varscan2
- KIF1B | c.2115+6694C>T | Intron (SNP) | VAF 19/46 reads (41%) | catalogued as COSV99823243; called by muse, mutect2, varscan2
- METTL15 | c.779-2282C>T | Intron (SNP) | VAF 30/63 reads (48%) | catalogued as COSV100328209; called by muse, mutect2, varscan2
- MIR1270 | chr19:20397847 G>A | 3'Flank (SNP) | VAF 19/64 reads (30%) | called by muse, mutect2, varscan2
- MTRNR2L6 | chr7:142671204 C>T | 3'Flank (SNP) | VAF 31/93 reads (33%) | catalogued as rs1333746250; called by muse, mutect2, varscan2
- NOVA1 | c.519+1855G>A | Intron (SNP) | VAF 10/25 reads (40%) | catalogued as COSV57474285, COSV99947544; called by muse, mutect2, varscan2
- OR3A4P | n.488G>A | RNA (SNP) | VAF 29/85 reads (34%) | called by muse, mutect2, varscan2
- TMPRSS3 | chr21:42396063 G>A | 5'Flank (SNP) | VAF 10/24 reads (42%) | catalogued as rs1195213322, COSV99368046; called by muse, mutect2, varscan2
- TPI1 | c.*246G>A | 3'UTR (SNP) | VAF 17/26 reads (65%) | catalogued as COSV51290524, COSV99222876; called by muse, mutect2, varscan2
- TRIM24 | c.*945C>T | 3'UTR (SNP) | VAF 27/74 reads (36%) | catalogued as rs1448060091, COSV100630951; called by muse, mutect2, varscan2
- TTLL8 | c.1087+12G>A | Intron (SNP) | VAF 11/31 reads (35%) | catalogued as rs1260425585, COSV99838307; called by muse, mutect2, varscan2
- TTN | c.10361-5001G>A | Intron (SNP) | VAF 53/130 reads (41%) | catalogued as COSV59976354; called by muse, mutect2, varscan2
- TTN | c.10360+1246C>T | Intron (SNP) | VAF 29/84 reads (35%) | catalogued as COSV100611802; called by muse, mutect2, varscan2
- VPS11 | c.-441C>T | 5'UTR (SNP) | VAF 27/62 reads (44%) | catalogued as COSV56185810; called by muse, mutect2, varscan2
